Somatic mutation profile of tumor specimen BA2915D (aliquot aq-BA2915D) from BEATAML1.0 case 2317, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 34.8 years (12,715 days).
Specimen BA2915D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7453977a-8447-4af3-9988-6d281fc217c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2599D (Solid Tissue Normal), aliquot aq-BA2599D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b842dd6-dff4-42bb-addc-4f2f357803f8

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- JAK3 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV71685795; called by muse, mutect2, varscan2
- PLXNA1 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs967938675; called by muse, mutect2
- VILL | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs372105661; called by muse, varscan2
- GLB1L2 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- OR2G6 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- PHACTR3 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TNXB | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
